CPTAC case C3L-02956 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4451889-5a3d-4296-8e87-6e22e036f9af

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1933; Vital status: Dead; Days to death: 164 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 84.1 years (30,711 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 164 days; Progression or recurrence: no; Days to last follow up: 164 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 16; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 164 days; Disease response: Progressive Disease.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02956-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 140 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02956-21: Section location: Body; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3L-02956-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 109 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02956-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
